Gene-level copy-number profile of tumor specimen HCM-SANG-0527-C18-01A-01D-A80T-32 from HCMI case HCM-SANG-0527-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0527-C18-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 06157992-0f2d-4c39-a64a-6cf5bf2eaa8a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0527-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,753 have no estimate.
https://portal.gdc.cancer.gov/files/f09e1ec7-a693-42c2-aa05-6bb6e91d58b4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 516; copy number 1: 3,993; copy number 2: 35,725; copy number 3: 12,452; copy number 4: 4,677; copy number 5: 1,478; copy number 6: 29.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,507 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:41,032,892–138,497,261, 1,366 genes, copy number 5–6 (broad region; genes not listed).
- chr8:139,727,725–140,458,579, 1 gene, copy number 5 (within-gene range 4–5): TRAPPC9.
- chr8:139,931,172–141,327,137, 22 genes, copy number 5: C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4.
- chr8:143,541,648–145,066,685, 112 genes, copy number 5 (broad region; genes not listed).
- chr13:20,777,329–20,949,599, 3 genes, copy number 5: XPO4, CNOT4P1, HNRNPA1P30.
- chr14:49,598,761–49,614,672, 3 genes, copy number 5 (within-gene range 2–5): LRR1, RHOQP1, AL139099.3.

Autosomal genes at a single copy (total copy number 1): 1,654. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
